Somatic mutation profile of tumor specimen TARGET-40-PAPWWC-01A (aliquot TARGET-40-PAPWWC-01A-01D) from TARGET case TARGET-40-PAPWWC, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 9.8 years (3,595 days).
Specimen TARGET-40-PAPWWC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdae20c7-936d-48d9-b652-957a7bf31057.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAPWWC-10A (Blood Derived Normal), aliquot TARGET-40-PAPWWC-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/662e22c8-734b-44eb-9307-8e87e4cf9f40

The open-access MAF lists 38 somatic variants for this specimen: 32 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Intron 2, Silent 2, 3'UTR 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD10 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs767277984; called by muse, mutect2, varscan2
- CASP7 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV61881418; called by muse, mutect2, varscan2
- CELA3A | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs775006416; called by muse, mutect2, varscan2
- CSMD3 | c.4165G>A p.G1389R (on ENST00000297405 / NM_001363185.1; = p.G1285R on NM_052900.3) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs750391997; called by muse, mutect2, varscan2
- DNAH2 | c.11353G>A p.E3785K | Missense Mutation (SNP) | VAF 63/771 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV66727243; called by muse, mutect2
- FGF8 | c.380G>A p.C127Y (on ENST00000344255 / NM_033164.4; = p.C109Y on NM_006119.6) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60143853; called by muse, mutect2
- GPR179 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.069); catalogued as rs778186164; called by muse, mutect2, varscan2
- HIRIP3 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV54228810; called by muse, mutect2, varscan2
- HIVEP1 | c.3451C>G p.P1151A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1406365211; called by muse, mutect2, varscan2
- OPN4 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.416); catalogued as rs753317541, COSV54116234; called by muse, mutect2, varscan2
- OR51E2 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV101211368; called by muse, mutect2, varscan2
- TMEM155 | c.318C>A p.S106R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.022); catalogued as rs1410749814; called by muse, varscan2
- TRAPPC12 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100160469; called by muse, mutect2
- UNC45A | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763110793; called by muse, mutect2, varscan2
- ZNF805 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs916845870; called by muse, mutect2, varscan2
- ATP23 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 59/954 reads (6%) | called by muse, mutect2
- CD163 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by mutect2, varscan2
- CNST | c.1795C>G p.L599V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CSMD3 | c.7022A>T p.D2341V (on ENST00000297405 / NM_001363185.1; = p.D2237V on NM_052900.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP3A4 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2
- EPN3 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- FAM13A | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM81B | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- GNA14 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MRPL21 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXDN | c.3884C>A p.P1295H | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RHAG | c.515T>A p.M172K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RNF214 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- S100A12 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- TNFRSF21 | c.656G>C p.S219T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VWF | c.5305C>A p.Q1769K | Missense Mutation (SNP) | VAF 84/97 reads (87%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WFDC10B | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GGNBP2 | c.120G>T p.V40= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- PLD6 | c.732C>T p.C244= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs775213418; called by mutect2, varscan2
- B4GALNT1 | c.*1585C>A | 3'UTR (SNP) | VAF 31/1335 reads (2%) | called by muse, mutect2
- CD44 | c.2024+661T>C | Intron (SNP) | VAF 4/41 reads (10%) | catalogued as rs1380600090; called by mutect2, varscan2
- ENSAP2 | n.328T>C | RNA (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- TRIM7 | c.618+68G>A | Intron (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
